Somatic mutation profile of tumor specimen MP2PRT-PARCMR-TMP1-A (aliquot MP2PRT-PARCMR-TMP1-A-1-0-D-A83B-36) from MP2PRT case MP2PRT-PARCMR, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.1 years (2,960 days).
Specimen MP2PRT-PARCMR-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2571868e-a9b9-4fa1-b25d-5b93162369b5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARCMR-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARCMR-NB1-A-1-0-D-A83B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/76488f14-85bb-42e5-b946-eb0531806430

The open-access MAF lists 28 somatic variants for this specimen: 18 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 17, Silent 10, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.205G>T p.E69* | Nonsense Mutation (SNP) | VAF 321/642 reads (50%) | catalogued as rs121913383, COSV58683264, COSV58724303, COSV58727969; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CREBBP | c.4415G>C p.W1472S | Missense Mutation (SNP) | VAF 172/332 reads (52%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52135188; called by muse, mutect2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 26/404 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- NRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 30/427 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- C8orf82 | c.328C>T p.R110W | Missense Mutation (SNP) | VAF 257/839 reads (31%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.809); catalogued as rs769144680; called by muse, mutect2, varscan2
- CSMD1 | c.3827C>T p.A1276V (on ENST00000520002; = p.A1275V on NM_033225.6) | Missense Mutation (SNP) | VAF 90/291 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.122); catalogued as rs200672229; called by muse, mutect2, varscan2
- FAM222B | c.443A>G p.Q148R | Missense Mutation (SNP) | VAF 77/684 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.205); catalogued as COSV57932601; called by muse, mutect2, varscan2
- GLI2 | c.1876G>A p.V626I (on ENST00000361492 / NM_001374353.1; = p.V643I on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 191/375 reads (51%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.447); catalogued as rs773204708, COSV58047544; called by muse, mutect2, varscan2
- NLRP5 | c.2510G>A p.R837H | Missense Mutation (SNP) | VAF 171/357 reads (48%) | SIFT tolerated (0.35); PolyPhen benign (0.112); catalogued as rs201517651, COSV66762771; called by muse, mutect2, varscan2
- OR2G6 | c.698G>T p.G233V | Missense Mutation (SNP) | VAF 136/307 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.565); catalogued as rs376461000; called by muse, mutect2, varscan2
- PCDH11X | c.455C>T p.S152L | Missense Mutation (SNP) | VAF 141/674 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); catalogued as COSV53463781; called by muse, mutect2, varscan2
- SCML2 | c.1412G>T p.R471M | Missense Mutation (SNP) | VAF 147/633 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0.01); catalogued as COSV52618105; called by muse, mutect2, varscan2
- STIM2 | c.245A>G p.D82G | Missense Mutation (SNP) | VAF 120/296 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52837226; called by muse, mutect2, varscan2
- SYNPO | c.2200C>T p.R734W (on ENST00000394243 / NM_001166208.2; = p.R490W on NM_007286.6) | Missense Mutation (SNP) | VAF 265/568 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56937924; called by muse, mutect2, varscan2
- THSD4 | c.1457G>A p.R486H | Missense Mutation (SNP) | VAF 196/400 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749505132; called by muse, mutect2, varscan2
- FLT3 | c.1764_1772delinsCCCCGGGCG p.E588_Y591delinsDPGR | Missense Mutation (ONP) | VAF 51/373 reads (14%) | called by pindel, varscan2*
- TCAF2 | c.2283C>A p.H761Q | Missense Mutation (SNP) | VAF 22/500 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- TFAP2E | c.385C>T p.R129C | Missense Mutation (SNP) | VAF 309/526 reads (59%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANGPT2 | c.864C>T p.F288= | Silent (SNP) | VAF 150/440 reads (34%) | called by muse, mutect2, varscan2
- CRAMP1 | c.1044C>T p.I348= | Silent (SNP) | VAF 165/361 reads (46%) | catalogued as rs371062747; called by muse, mutect2, varscan2
- DNAH2 | c.2844C>T p.N948= | Silent (SNP) | VAF 198/646 reads (31%) | catalogued as rs753977609; called by muse, mutect2, varscan2
- KCTD19 | c.627C>T p.S209= | Silent (SNP) | VAF 68/205 reads (33%) | catalogued as rs755940431; called by muse, mutect2, varscan2
- KIF21B | c.4284C>T p.Y1428= (on ENST00000422435 / NM_001252100.2; = p.Y1415= on NM_017596.4) | Silent (SNP) | VAF 157/349 reads (45%) | catalogued as rs377370935; called by muse, mutect2, varscan2
- LOX | c.297C>T p.T99= | Silent (SNP) | VAF 308/635 reads (49%) | catalogued as rs1289856512; called by muse, mutect2, varscan2
- PCDH8 | c.1050C>T p.N350= | Silent (SNP) | VAF 354/746 reads (47%) | catalogued as rs1246198933, COSV58812667; called by muse, mutect2, varscan2
- RFX4 | c.1302C>T p.F434= (on ENST00000392842 / NM_213594.3; = p.F340= on NM_032491.6) | Silent (SNP) | VAF 87/450 reads (19%) | catalogued as rs144713941; called by muse, mutect2, varscan2
- SLC10A6 | c.1005G>A p.S335= | Silent (SNP) | VAF 24/408 reads (6%) | catalogued as rs149919322, COSV56721301; called by muse, mutect2
- TLR7 | c.867G>T p.L289= | Silent (SNP) | VAF 211/1016 reads (21%) | called by muse, mutect2, varscan2
